MMRF case MMRF_2573 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3fa693fe-27d0-48da-8c41-d740747ec62a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.7 years (26,564 days); ISS stage: II; Days to last known disease status: 649 days (1.8 years); Days to last follow up: 649 days (1.8 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 268 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 268 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 268 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 95 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 515 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.986 mg/dL; Immunoglobulin G 6.69 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 4.25 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 75 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 5.28 mmol/L; Calcium 2.73 mmol/L; Albumin 48 g/L; Total Protein 7.2 g/dL; Glucose 5.12 mmol/L.
- Day 85 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 4.55 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 86 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.13 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 5.5 mmol/L.
- Day 169 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.71 mg/dL; Immunoglobulin G 5.6 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.78 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 3.51 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 133 µmol/L; Calcium 2.25 mmol/L; Glucose 4.57 mmol/L.
- Day 253 (ECOG 0): Hemoglobin 6.08 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.63 ×10⁹/L; Platelets 91 ×10⁹/L.
- Day 347 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 6.09 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 9.89 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 5.89 mmol/L.
- Day 428 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.02 mg/dL; Immunoglobulin G 7.11 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.87 ×10⁹/L; Platelets 86 ×10⁹/L; Creatinine 133 µmol/L; Calcium 2.3 mmol/L; Glucose 6.99 mmol/L.
- Day 537 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.57 mg/dL; Immunoglobulin G 8.13 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.44 ×10⁹/L; Platelets 74 ×10⁹/L; Creatinine 124 µmol/L; Calcium 2.3 mmol/L; Glucose 5.34 mmol/L.
- Day 649 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.57 mg/dL; Immunoglobulin G 9.12 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 0.66 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.25 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL.

Other clinical attributes
- Day -9: Weight: 88 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2573_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_2573_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
